Somatic mutation profile of tumor specimen 0DC2A0 from CCDI case PBBLRV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Synovial sarcoma, spindle cell; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 6.2 years (2,247 days).
Specimen 0DC2A0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfe6bd28-88b2-4b5b-a477-54bb2356a5d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DC29Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fbc60f5-0681-4e44-a150-d52f87194f2b

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM205A | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 140/358 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs559668831, COSV66489321; called by muse, mutect2, varscan2
- HTR3D | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 137/296 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61913669; called by muse, mutect2, varscan2
- FNDC7 | c.752G>A p.C251Y | Missense Mutation (SNP) | VAF 35/632 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TNS1 | c.1006T>A p.W336R | Missense Mutation (SNP) | VAF 79/673 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- AKR1C8P | c.348C>G p.L116= | Silent (SNP) | VAF 221/546 reads (40%) | catalogued as rs1267671310; called by muse, mutect2, varscan2
- GNB5 | c.1149C>T p.C383= (on ENST00000261837 / NM_016194.4; = p.C341= on NM_006578.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/790 reads (8%) | catalogued as COSV55897983; called by muse, mutect2
- OR2T33 | c.962G>A p.*321= | Silent (SNP) | VAF 49/403 reads (12%) | catalogued as COSV58815423; called by muse, varscan2
- RAB5B | c.360A>G p.R120= | Silent (SNP) | VAF 51/396 reads (13%) | called by muse, mutect2, varscan2
- SIGLEC14 | c.468C>T p.S156= | Silent (SNP) | VAF 120/505 reads (24%) | catalogued as rs556350510; called by muse, varscan2
- FMO5 | c.324+13G>T | Intron (SNP) | VAF 168/322 reads (52%) | called by muse, mutect2, varscan2
